Somatic mutation profile of tumor specimen TCGA-34-7107-01A (aliquot TCGA-34-7107-01A-11D-1945-08) from TCGA case TCGA-34-7107, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 70.3 years (25,677 days).
Specimen TCGA-34-7107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c38abf2f-8a2c-4ec3-89c9-9842e158a087.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-7107-10A (Blood Derived Normal), aliquot TCGA-34-7107-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cee86ad-a58e-4292-8bf1-234e56deeb23

The open-access MAF lists 289 somatic variants for this specimen: 208 protein-altering or splice-affecting, 72 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 72, Nonsense Mutation 17, Frame Shift Del 10, Intron 5, Splice Site 4, Splice Region 3, RNA 3, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 46/90 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, varscan2
- WT1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1037084691, CM148987, COSV60067835, COSV60069216, COSV60071337, COSV60072267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3089T>C p.L1030P | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99288326; called by muse, mutect2, varscan2
- ACOT8 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs750307207, COSV99467470; called by muse, mutect2, varscan2
- ADCY7 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575662, COSV99575850; called by muse, mutect2, varscan2
- ANKRD52 | c.2650G>C p.V884L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV99921202; called by muse, mutect2, varscan2
- ANKS1B | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101612660; called by muse, mutect2, varscan2
- ANKS3 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100423029; called by muse, mutect2, varscan2
- ATP10D | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1162198061, COSV99905450; called by muse, mutect2, varscan2
- ATP2A3 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs150069192; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100376942; called by muse, mutect2, varscan2
- BANP | c.1278G>T p.Q426H (on ENST00000286122; = p.Q398H on NM_017869.4) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV99621275; called by muse, mutect2, varscan2
- BOC | c.1173C>A p.C391* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99848473; called by muse, mutect2, varscan2
- BPIFA3 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 78/127 reads (61%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV100967036; called by muse, mutect2, varscan2
- BRCA1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV100523802, COSV58796517; called by muse, mutect2, varscan2
- BRF1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100527124; called by muse, mutect2, varscan2
- BRINP3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.026); catalogued as COSV100818610; called by muse, mutect2, varscan2
- BROX | c.93A>C p.K31N | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100388171; called by muse, mutect2, varscan2
- C3orf56 | c.456C>A p.H152Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV101228943, COSV67756562; called by muse, mutect2, varscan2
- CADPS2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV57362475, COSV57364407; called by muse, mutect2, varscan2
- CALCA | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.167); catalogued as COSV100523979; called by muse, mutect2
- CATSPERG | c.3100T>A p.L1034M | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as COSV99286322; called by muse, mutect2, varscan2
- CBLB | c.2055-1G>T p.X685_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99913172, COSV99913811; called by muse, mutect2
- CCNJL | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs377363287; called by muse, mutect2, varscan2
- CD244 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs564725344, COSV100458395; called by muse, mutect2, varscan2
- CEACAM3 | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 267/559 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs782030023, COSV99704916; called by muse, mutect2, varscan2
- CEP170 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100316815; called by muse, mutect2, varscan2
- CEP170 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839652, COSV100839904; called by muse, mutect2, varscan2
- CILP2 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99364532; called by muse, mutect2, varscan2
- CISD1 | c.238-2A>T p.X80_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100445687; called by muse, mutect2, varscan2
- CLCC1 | c.1141C>T p.R381W (on ENST00000356970 / NM_001377464.1; = p.R331W on NM_015127.5) | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs747968236, COSV100206366; called by muse, mutect2, varscan2
- CPAMD8 | c.3545A>G p.N1182S (on ENST00000651564; = p.N1135S on NM_015692.5) | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs762321466, COSV101488461; called by muse, mutect2, varscan2
- CPS1 | c.2872C>A p.L958I | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV51810433, COSV99242654; called by muse, mutect2, varscan2
- CRADD | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV100257504; called by muse, mutect2, varscan2
- CRB1 | c.2483A>G p.D828G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100957787; called by muse, varscan2
- CSMD1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV68200786, COSV68268637; called by muse, mutect2, varscan2
- CSMD2 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.804); catalogued as rs777263781; called by muse, mutect2, varscan2
- CSMD3 | c.7580C>A p.S2527Y (on ENST00000297405 / NM_001363185.1; = p.S2423Y on NM_052900.3) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV52231979, COSV99830652; called by muse, mutect2, varscan2
- CSMD3 | c.5734G>T p.G1912* (on ENST00000297405 / NM_001363185.1; = p.G1808* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV52119825, COSV52211131; called by muse, mutect2, varscan2
- CSMD3 | c.5477C>T p.S1826F (on ENST00000297405 / NM_001363185.1; = p.S1722F on NM_052900.3) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as COSV99830660; called by muse, mutect2, varscan2
- CTNNA3 | c.2228C>G p.S743* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | catalogued as COSV101041333; called by muse, mutect2, varscan2
- CYLC1 | c.1881C>G p.C627W | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100254404; called by muse, mutect2, varscan2
- CYP2R1 | c.188A>G p.H63R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs903347739, COSV100584889; called by muse, mutect2, varscan2
- DIO2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV70445739; called by muse, mutect2, varscan2
- DNAH17 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372647934; called by muse, mutect2, varscan2
- DNAH7 | c.1943C>G p.A648G | Missense Mutation (SNP) | VAF 121/208 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100414639; called by muse, mutect2, varscan2
- DNAH8 | c.2044G>T p.V682L | Missense Mutation (SNP) | VAF 96/120 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100544278, COSV100547363; called by muse, varscan2
- DPPA2 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.388); catalogued as COSV101524751; called by muse, mutect2, varscan2
- EBF2 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV101282136, COSV68776525; called by muse, mutect2, varscan2
- EGF | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99490720; called by muse, mutect2, varscan2
- EIF2B5 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 46/1201 reads (4%) | catalogued as COSV99889147; called by muse, mutect2
- EIF3A | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV100974565; called by muse, mutect2, varscan2
- ELMO1 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100163967; called by muse, mutect2, varscan2
- EPB41L3 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100548637, COSV59445346; called by muse, mutect2, varscan2
- ERVW-1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101423824; called by muse, mutect2
- ETFB | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100164296; called by muse, mutect2, varscan2
- FAT4 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766427266, COSV58670665; called by muse, mutect2, varscan2
- FBXL13 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100501406; called by mutect2, varscan2
- FBXO10 | c.2680C>G p.L894V | Missense Mutation (SNP) | VAF 200/265 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV99446477; called by muse, mutect2, varscan2
- FBXO34 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs772815143, COSV58253613, COSV58255686; called by muse, mutect2, varscan2
- FLG2 | c.1051A>G p.S351G | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101165769; called by muse, mutect2, varscan2
- FNDC1 | c.2153G>T p.R718I | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV99795426; called by muse, mutect2, varscan2
- FOXB1 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101249749; called by muse, mutect2, varscan2
- GFM1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV51831936; called by muse, mutect2, varscan2
- GJD3 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747555215, COSV100492223; called by muse, varscan2
- GLDC | c.1059-1G>T p.X353_splice | Splice Site (SNP) | VAF 57/71 reads (80%) | catalogued as COSV58676910; called by muse, mutect2, varscan2
- GPD2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1250662732, COSV100133135; called by muse, mutect2, varscan2
- GPRIN2 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100966347; called by muse, mutect2
- GRAMD1B | c.540G>A p.K180= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100454560; called by muse, mutect2, varscan2
- GRAMD4 | c.717C>T p.T239= | Splice Region (SNP) | VAF 44/150 reads (29%) | catalogued as rs147561076; called by muse, mutect2, varscan2
- GRK7 | c.1223T>A p.L408Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.377); catalogued as COSV99379736; called by muse, mutect2, varscan2
- GRM1 | c.2264C>A p.A755D | Missense Mutation (SNP) | VAF 129/181 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265326; called by muse, mutect2, varscan2
- HDAC4 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100613137; called by muse, mutect2, varscan2
- HELB | c.1019A>T p.D340V | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99921751; called by muse, mutect2, varscan2
- KCND2 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV100474878; called by muse, mutect2, varscan2
- KCNH1 | c.2780T>C p.L927P (on ENST00000271751 / NM_172362.3; = p.L900P on NM_002238.4) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.418); catalogued as COSV99658456; called by muse, mutect2, varscan2
- KCNH7 | c.2035C>G p.Q679E | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV100035090, COSV59800542; called by muse, mutect2, varscan2
- KIAA0586 | c.986G>T p.R329L (on ENST00000619416 / NM_001244190.2; = p.R344L on NM_014749.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99039108, COSV99707856; called by muse, mutect2, varscan2
- KIAA1109 | c.6326T>C p.L2109P | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99151371; called by muse, mutect2, varscan2
- KIAA1522 | c.235C>T p.Q79* (on ENST00000373480 / NM_001198972.2; = p.Q138* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as COSV99614447; called by muse, mutect2, varscan2
- KIF13B | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101580578; called by muse, mutect2, varscan2
- KIF21A | c.4735G>C p.V1579L (on ENST00000361418 / NM_001378440.1; = p.V1566L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.12); catalogued as COSV100735386; called by muse, mutect2, varscan2
- KIF2B | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52135781, COSV99082061; called by muse, mutect2, varscan2
- KIRREL2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99383834; called by muse, mutect2, varscan2
- KMT2C | c.10399G>T p.G3467* | Nonsense Mutation (SNP) | VAF 144/286 reads (50%) | catalogued as COSV100070215; called by muse, mutect2, varscan2
- KMT2D | c.11212C>T p.Q3738* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99040365; called by muse, mutect2, varscan2
- KRT12 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99288886; called by muse, mutect2, varscan2
- LAMA2 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as rs781424807, COSV101370333; called by muse, mutect2, varscan2
- LAMP5 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1272062378, COSV99855529; called by muse, mutect2, varscan2
- LIPT1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100399407; called by muse, mutect2, varscan2
- LMTK2 | c.1089T>G p.I363M | Missense Mutation (SNP) | VAF 98/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99806547; called by muse, mutect2, varscan2
- LOXL2 | c.1216A>T p.K406* | Nonsense Mutation (SNP) | VAF 40/114 reads (35%) | catalogued as COSV101207847; called by muse, mutect2, varscan2
- LRP1 | c.4282C>T p.R1428W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs745902553, COSV99675393; called by muse, mutect2, varscan2
- LRP1B | c.9952A>T p.T3318S | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101255042, COSV101258177; called by muse, mutect2, varscan2
- LRP2 | c.8900C>T p.P2967L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99787585; called by muse, mutect2, varscan2
- LTBP2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV100000067; called by muse, mutect2, varscan2
- LTV1 | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 103/146 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770665905, COSV99394287; called by muse, mutect2, varscan2
- MAN2B1 | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666875; called by muse, mutect2, varscan2
- MANEA | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100721486; called by muse, mutect2, varscan2
- MAP1B | c.6109A>G p.T2037A | Missense Mutation (SNP) | VAF 97/149 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99702133; called by muse, mutect2, varscan2
- MAPT | c.1998G>C p.K666N (on ENST00000262410 / NM_001377265.1; = p.K274N on NM_005910.5) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99290209; called by muse, mutect2, varscan2
- MAS1L | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 95/146 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as COSV101009668; called by muse, mutect2, varscan2
- MCF2L | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV100985165; called by muse, mutect2, varscan2
- MEFV | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs377250147; called by muse, mutect2, varscan2
- MFAP5 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100848122; called by muse, varscan2
- MTERF3 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1316140187, COSV54633462; called by muse, mutect2, varscan2
- MYH8 | c.3164A>T p.K1055M | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101238356; called by muse, mutect2, varscan2
- MYO18B | c.6716C>A p.S2239* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV100123211, COSV59145660; called by muse, mutect2, varscan2
- N4BP1 | c.2395G>T p.V799F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.072); catalogued as COSV99285030; called by muse, mutect2, varscan2
- NANOS3 | c.440G>A p.R147Q (on ENST00000397555; = p.R166Q on NM_001098622.2) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs866979059, COSV100188472; called by muse, varscan2
- NCKAP5 | c.2042T>C p.F681S | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100491197; called by muse, mutect2, varscan2
- NT5C3B | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505155; called by muse, mutect2, varscan2
- NUDT12 | c.1022G>T p.R341M | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100048110; called by muse, mutect2, varscan2
- OR10G7 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100389875; called by muse, mutect2
- OR10Z1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 134/341 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100778987, COSV63524409; called by muse, mutect2, varscan2
- OR11H4 | c.156T>A p.N52K | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100197462; called by muse, mutect2, varscan2
- OR13A1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100981000; called by muse, mutect2, varscan2
- OR1S2 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100224092; called by muse, mutect2, varscan2
- OR52A1 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753480016, COSV100200460; called by muse, mutect2, varscan2
- OR52I2 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100442877; called by muse, mutect2, varscan2
- OR5M8 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765019954, COSV100510621; called by muse, mutect2, varscan2
- OR6C3 | c.229A>T p.R77* | Nonsense Mutation (SNP) | VAF 94/196 reads (48%) | catalogued as COSV101110342; called by muse, mutect2, varscan2
- OR8A1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.015); catalogued as COSV99420473; called by muse, mutect2, varscan2
- OTOGL | c.4604G>T p.R1535L (on ENST00000547103; = p.R1526L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100087058; called by muse, mutect2, varscan2
- PARP1 | c.285A>T p.T95= | Splice Region (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100828514; called by muse, mutect2, varscan2
- PDE4DIP | c.3307A>G p.R1103G | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV57717982; called by mutect2, varscan2
- PFKP | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747886663, COSV101126697; called by muse, mutect2, varscan2
- PJVK | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 87/140 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs1259052199, COSV100910472; called by muse, mutect2, varscan2
- PKHD1 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100582394; called by muse, mutect2, varscan2
- PKHD1L1 | c.5140A>T p.T1714S | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101005906; called by muse, mutect2, varscan2
- PKHD1L1 | c.9658G>C p.D3220H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV101005907, COSV65739362; called by muse, mutect2, varscan2
- PKLR | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.956); catalogued as COSV100712865; called by muse, mutect2, varscan2
- PLA2G3 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV99311508; called by muse, mutect2, varscan2
- PLEC | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs782783624, COSV100512714; called by muse, mutect2, varscan2
- PLG | c.1118T>A p.V373E | Missense Mutation (SNP) | VAF 95/136 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV99804516; called by muse, mutect2, varscan2
- PNLIP | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.049); catalogued as COSV100981744; called by muse, mutect2, varscan2
- PNPLA7 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs778567963, COSV99480443; called by muse, mutect2, varscan2
- POSTN | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123299, COSV65712368; called by muse, mutect2, varscan2
- PRKN | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58202909, COSV58220892, COSV58225018; called by muse, mutect2, varscan2
- PRR30 | c.1074G>C p.R358S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as rs767273333, COSV99574420; called by muse, mutect2, varscan2
- PTPRB | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99716788; called by muse, mutect2, varscan2
- PTPRC | c.3802C>G p.P1268A | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100722437; called by muse, mutect2, varscan2
- PTPRK | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 94/125 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs1439009896, COSV100949550; called by muse, mutect2, varscan2
- RALGAPA2 | c.5171G>C p.R1724P | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173360; called by muse, mutect2
- RAPH1 | c.1168T>C p.C390R (on ENST00000319170 / NM_213589.3; = p.C442R on NM_203365.4) | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100051347; called by muse, mutect2, varscan2
- RASAL3 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as rs1175003446, COSV100640281; called by muse, mutect2
- ROS1 | c.6723A>T p.E2241D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100876871; called by muse, mutect2, varscan2
- RPL10 | c.154A>T p.M52L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99185873; called by muse, mutect2
- RSAD2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65908003; called by muse, mutect2, varscan2
- RUNX1T1 | c.500C>T p.S167F (on ENST00000265814 / NM_001198628.1; = p.S140F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as rs760524107, COSV56138314, COSV99750977; called by muse, mutect2, varscan2
- RYR2 | c.7188T>G p.I2396M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100769332; called by muse, mutect2
- SASH1 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100821107; called by muse, mutect2, varscan2
- SERPINB7 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320351; called by muse, mutect2, varscan2
- SERTAD4 | c.175+1G>C p.X59_splice | Splice Site (SNP) | VAF 41/97 reads (42%) | catalogued as COSV100882599; called by muse, mutect2, varscan2
- SLAMF6 | c.880G>A p.E294K (on ENST00000368057 / NM_001184714.2; = p.E293K on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as COSV100924865; called by muse, mutect2, varscan2
- SLC12A1 | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100372285, COSV104397918; called by muse, mutect2, varscan2
- SLC20A1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV55611769, COSV55612392, COSV99733981; called by muse, mutect2
- SLC2A13 | c.664T>A p.F222I | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99786306; called by muse, mutect2, varscan2
- SLCO1C1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs1261143962, COSV99858863; called by muse, mutect2, varscan2
- SNED1 | c.1462T>C p.C488R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122505; called by muse, mutect2, varscan2
- SNX13 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101296819, COSV101296924; called by muse, mutect2, varscan2
- SPATA31E1 | c.3853G>T p.D1285Y | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100350226; called by muse, mutect2, varscan2
- STON2 | c.2528A>C p.H843P (on ENST00000649389 / NM_001366849.2; = p.H786P on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.71); catalogued as COSV99964620; called by muse, mutect2, varscan2
- TAGAP | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 96/143 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100487361; called by muse, mutect2, varscan2
- TAS2R1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs927677193, COSV66778737, COSV66778995; called by muse, mutect2, varscan2
- TCAF2 | c.914C>G p.T305R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100633753; called by mutect2, varscan2
- TEC | c.1601C>G p.P534R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972340; called by muse, mutect2, varscan2
- TIAM1 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 123/217 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99734236; called by muse, mutect2, varscan2
- TMCC1 | c.1595G>T p.S532I (on ENST00000393238 / NM_001349268.2; = p.S208I on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100260893; called by muse, mutect2, varscan2
- TNK2 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as COSV100361167; called by muse, mutect2
- TOX3 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 41/262 reads (16%) | catalogued as COSV99567360; called by muse, mutect2, varscan2
- TRAV1-1 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1245984240; called by muse, mutect2, varscan2
- TRIM62 | c.908C>A p.T303K | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52221194, COSV99357739; called by muse, mutect2, varscan2
- TTN | c.65911G>A p.G21971R (on ENST00000591111; = p.G14547R on NM_003319.4) | Missense Mutation (SNP) | VAF 94/128 reads (73%) | PolyPhen probably damaging (1); catalogued as COSV59966144; called by muse, mutect2, varscan2
- TTN | c.26686C>A p.P8896T (on ENST00000591111; = p.P7969T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/271 reads (15%) | PolyPhen probably damaging (0.91); catalogued as COSV100604382; called by muse, mutect2, varscan2
- UNC13C | c.6011G>A p.S2004N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52845226; called by muse, mutect2, varscan2
- VCAN | c.4393G>C p.V1465L | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99425331; called by muse, mutect2, varscan2
- VWC2 | c.949T>C p.C317R | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100514061; called by muse, mutect2, varscan2
- WDR53 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100218044; called by muse, mutect2
- WDR86 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs373857242; called by muse, mutect2, varscan2
- XKR5 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101306644; called by muse, mutect2, varscan2
- ZNF117 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV99275418; called by muse, mutect2, varscan2
- ZNF280B | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100840236; called by muse, mutect2, varscan2
- ZNF417 | c.1315A>T p.R439W | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV100364165; called by muse, varscan2
- ZNF438 | c.1674T>A p.H558Q | Missense Mutation (SNP) | VAF 121/308 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767028694, COSV100061591; called by muse, mutect2, varscan2
- ZNF462 | c.3083T>A p.V1028D | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99471366; called by muse, mutect2, varscan2
- ZNF551 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs772666359, COSV99989890; called by muse, mutect2, varscan2
- ZNF613 | c.592C>T p.Q198* (on ENST00000293471 / NM_001031721.4; = p.Q162* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 206/309 reads (67%) | catalogued as COSV53270896, COSV99522885; called by muse, mutect2, varscan2
- ZNF778 | c.1478C>G p.T493S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100124366, COSV104403853; called by muse, mutect2, varscan2
- ZNF786 | c.71A>C p.Q24P | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100302779; called by muse, mutect2, varscan2
- ZNF804A | c.2235G>A p.M745I | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs920464482, COSV56435661; called by muse, mutect2, varscan2
- ZNF804A | c.3022A>G p.K1008E | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100167282; called by muse, mutect2, varscan2
- AMER3 | c.493del p.H165Tfs*101 | Frame Shift Del (DEL) | VAF 64/189 reads (34%) | called by mutect2, pindel, varscan2
- CD1D | c.639dup p.S214Qfs*29 | Frame Shift Ins (INS) | VAF 55/176 reads (31%) | called by mutect2, pindel, varscan2
- CLSTN2 | c.1396del p.V466* | Frame Shift Del (DEL) | VAF 48/146 reads (33%) | called by mutect2, pindel, varscan2
- FAT1 | c.5564del p.P1855Hfs*11 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by pindel, varscan2*
- FAT2 | c.1731dup p.P578Afs*16 | Frame Shift Ins (INS) | VAF 42/97 reads (43%) | called by mutect2, pindel, varscan2
- FCGBP | c.6793G>T p.A2265S | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HTR3A | c.945del p.L316Wfs*2 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 121/328 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IL18RAP | c.1217del p.K406Rfs*23 | Frame Shift Del (DEL) | VAF 43/119 reads (36%) | called by mutect2, pindel, varscan2
- LRP1B | c.10076del p.P3359Qfs*54 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- MRPS17 | c.123+1del | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | called by mutect2, pindel, varscan2
- OR14A16 | c.750del p.T251Lfs*7 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- RERE | c.4354del p.V1452Ffs*8 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | called by mutect2, pindel, varscan2
- RYR3 | c.10926del p.M3643Wfs*6 (on ENST00000389232; = p.M3644Wfs*6 on NM_001036.6) | Frame Shift Del (DEL) | VAF 36/77 reads (47%) | called by mutect2, pindel, varscan2
- TRAV34 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCA7 | c.2601C>T p.I867= | Silent (SNP) | VAF 107/185 reads (58%) | catalogued as rs922909214, COSV99565526; called by muse, mutect2, varscan2
- ADGRG4 | c.3228T>C p.V1076= | Silent (SNP) | VAF 473/527 reads (90%) | catalogued as COSV99795087; called by muse, mutect2, varscan2
- ANK2 | c.4593T>C p.S1531= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV100000847; called by muse, mutect2, varscan2
- AP3D1 | c.3171C>A p.A1057= | Silent (SNP) | VAF 71/303 reads (23%) | catalogued as COSV100642564; called by muse, mutect2, varscan2
- APOBEC3F | c.321G>C p.L107= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as rs560517594, COSV100415157; called by muse, mutect2, varscan2
- BTBD1 | c.837G>A p.L279= | Silent (SNP) | VAF 71/119 reads (60%) | catalogued as COSV99915386; called by muse, mutect2, varscan2
- CACNA1E | c.4662C>T p.I1554= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100701910; called by muse, mutect2, varscan2
- CALCR | c.1119C>A p.V373= (on ENST00000649521 / NM_001164737.2; = p.V357= on NM_001742.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100810471; called by muse, mutect2, varscan2
- CCDC39 | c.1833G>A p.A611= | Silent (SNP) | VAF 44/570 reads (8%) | catalogued as rs371164022; ClinVar: uncertain significance; called by muse, mutect2
- CHD9 | c.4239A>T p.T1413= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV99529013; called by muse, mutect2, varscan2
- CLVS1 | c.240C>T p.L80= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV100369725; called by muse, mutect2, varscan2
- COG5 | c.1281A>G p.Q427= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs1327142509, COSV99771802; called by muse, mutect2, varscan2
- CTNNA3 | c.1146A>T p.I382= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV101048121; called by muse, mutect2, varscan2
- CTNND2 | c.2104C>A p.R702= | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as COSV58868050, COSV58920204; called by muse, mutect2, varscan2
- CUBN | c.1542C>T p.I514= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV64711219; called by muse, mutect2, varscan2
- DBF4B | c.252A>G p.E84= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV100154429; called by muse, mutect2, varscan2
- DISP3 | c.2205G>C p.L735= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV99608125; called by muse, mutect2, varscan2
- EN1 | c.261G>C p.A87= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99727106; called by muse, mutect2, varscan2
- EPHB4 | c.2490C>T p.I830= | Silent (SNP) | VAF 31/167 reads (19%) | catalogued as rs1327625490, COSV100639465; called by muse, mutect2, varscan2
- FCGBP | c.2298G>A p.A766= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1224313538; called by muse, mutect2, varscan2
- FOXA2 | c.210C>G p.G70= (on ENST00000377115 / NM_153675.3; = p.G76= on NM_021784.5) | Silent (SNP) | VAF 78/122 reads (64%) | catalogued as COSV101008303; called by muse, varscan2
- GCNT1 | c.1224C>G p.L408= | Silent (SNP) | VAF 7/198 reads (4%) | catalogued as COSV100946502; called by muse, mutect2
- GEMIN4 | c.1716C>T p.L572= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs767791810, COSV56748332; called by muse, mutect2, varscan2
- GGPS1 | c.168G>A p.L56= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99270404; called by muse, mutect2, varscan2
- GLG1 | c.2466A>G p.L822= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs760558405, COSV99215592; called by muse, mutect2, varscan2
- HCLS1 | c.1359C>T p.D453= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs148435056; called by muse, mutect2, varscan2
- KIT | c.2919C>T p.H973= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs755974085, COSV55434384; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP3K1 | c.3828T>C p.Y1276= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs372801625; called by muse, mutect2, varscan2
- MAPK15 | c.1515T>A p.S505= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as COSV100567798; called by muse, mutect2, varscan2
- MEFV | c.1614T>G p.A538= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV99560622; called by muse, mutect2, varscan2
- MRC1 | c.1956C>T p.A652= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.534C>T p.F178= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100245937; called by muse, mutect2
- MUC17 | c.7716A>T p.G2572= | Silent (SNP) | VAF 136/603 reads (23%) | catalogued as COSV100072634; called by muse, mutect2, varscan2
- MYH13 | c.5277C>T p.A1759= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV99353336; called by muse, mutect2, varscan2
- MYH3 | c.2460C>G p.R820= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99878028; called by muse, mutect2, varscan2
- MYT1L | c.1830G>A p.K610= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV101219940; called by muse, mutect2, varscan2
- NANOS3 | c.441A>G p.R147= (on ENST00000397555; = p.R166= on NM_001098622.2) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100188473; called by muse, varscan2
- NLGN4X | c.645C>T p.D215= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV52023856, COSV99321045; called by muse, mutect2, varscan2
- OR2F2 | c.222C>T p.A74= | Silent (SNP) | VAF 169/354 reads (48%) | catalogued as COSV101283808, COSV68832726; called by muse, mutect2, varscan2
- OR2T8 | c.165G>A p.T55= | Silent (SNP) | VAF 52/180 reads (29%) | catalogued as rs562352417, COSV60662094, COSV60664997; called by muse, varscan2
- OR8A1 | c.696G>A p.G232= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV52508725; called by muse, mutect2, varscan2
- OR8U1 | c.342A>G p.L114= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV100163856; called by muse, varscan2
- PABPC1L | c.789G>T p.A263= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV99407701; called by muse, mutect2, varscan2
- PABPC3 | c.852G>A p.K284= | Silent (SNP) | VAF 28/254 reads (11%) | catalogued as rs781765701, COSV55797011; called by muse, mutect2, varscan2
- PHKB | c.1818A>G p.K606= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs780273839, COSV100066454; called by muse, mutect2, varscan2
- PPP3R2 | c.177C>T p.I59= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV62455252; called by muse, mutect2
- PRDM9 | c.1855C>A p.R619= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as COSV57003012, COSV99690213; called by muse, varscan2
- PRKD1 | c.2196G>T p.R732= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100119836; called by muse, mutect2, varscan2
- RAD51AP2 | c.690T>A p.S230= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV101208314; called by muse, mutect2, varscan2
- RAG1 | c.249C>T p.A83= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV100200813; called by muse, mutect2, varscan2
- RP1 | c.1551T>A p.L517= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99606993; called by muse, mutect2, varscan2
- SCN3A | c.3408C>A p.T1136= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV99326434; called by muse, mutect2, varscan2
- SERPINH1 | c.543C>T p.T181= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs1166332198, COSV100825045, COSV100825097; called by muse, mutect2, varscan2
- SHMT2 | c.351G>A p.L117= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs745814583, COSV100197122; called by muse, mutect2, varscan2
- SLC26A3 | c.1605G>C p.V535= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100384975, COSV60640401; called by muse, mutect2, varscan2
- SLC4A11 | c.1299G>A p.L433= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV101195927; called by muse, mutect2, varscan2
- SLC5A4 | c.1869G>A p.L623= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as COSV56668585; called by muse, mutect2, varscan2
- SLC7A6 | c.780C>A p.I260= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs759611561, COSV99546511; called by muse, mutect2, varscan2
- SPNS2 | c.477C>A p.G159= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100223553; called by muse, mutect2, varscan2
- SPTA1 | c.4296G>A p.L1432= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV63751732, COSV63753642; called by muse, mutect2, varscan2
- SPTA1 | c.3780G>A p.L1260= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV100934687; called by muse, mutect2, varscan2
- STAB2 | c.7653G>A p.L2551= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV101185814; called by muse, mutect2, varscan2
- STAM2 | c.1431C>T p.Y477= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV99812959; called by muse, mutect2, varscan2
- TET1 | c.3519G>A p.R1173= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs1322547157, COSV101017898; called by muse, mutect2, varscan2
- TIMM44 | c.477G>A p.S159= | Silent (SNP) | VAF 20/201 reads (10%) | catalogued as rs749770608, COSV54493091; called by muse, mutect2, varscan2
- TMEM132D | c.2199G>A p.L733= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV101242710, COSV101243164; called by muse, mutect2, varscan2
- TMEM169 | c.738G>C p.R246= | Silent (SNP) | VAF 77/131 reads (59%) | catalogued as COSV99824450; called by muse, mutect2, varscan2
- TMEM199 | c.447C>T p.T149= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs782816323, COSV99134740; called by muse, mutect2, varscan2
- TTLL8 | c.324A>G p.E108= | Silent (SNP) | VAF 102/217 reads (47%) | catalogued as COSV99838206; called by muse, mutect2, varscan2
- UTS2B | c.151T>C p.L51= | Silent (SNP) | VAF 85/134 reads (63%) | catalogued as COSV61280634; called by muse, mutect2, varscan2
- WFIKKN1 | c.765C>T p.P255= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs759915390, COSV99937661; called by muse, mutect2, varscan2
- ZNF324 | c.1661G>A p.*554= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99543222; called by muse, mutect2, varscan2
- AC074085.2 | n.25G>A | RNA (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.423G>A | RNA (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2537G>C | 3'UTR (SNP) | VAF 46/159 reads (29%) | catalogued as COSV57067967, COSV99950186; called by muse, mutect2, varscan2
- MIR512-1 | n.66T>A | RNA (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- PPM1K | c.542-2245G>C | Intron (SNP) | VAF 13/19 reads (68%) | catalogued as COSV99900918; called by muse, mutect2, varscan2
- SIRT5 | c.857+3547C>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100702770; called by muse, mutect2, varscan2
- SPRED3 | c.424-256del | Intron (DEL) | VAF 52/210 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.10360+4145A>G | Intron (SNP) | VAF 25/242 reads (10%) | catalogued as COSV100604383, COSV59956880; called by muse, mutect2, varscan2
- TTN | c.10303+2195C>T | Intron (SNP) | VAF 34/168 reads (20%) | catalogued as COSV100604386; called by muse, mutect2, varscan2
